Surgical pathology report (de-identified scan), TCGA case TCGA-06-0413, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0413-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

MRN:

Birth Date:

Sex: Female Room/Bed:

PATIENT NAME:

HC NO.:

AGE/SEX:

F

ACC. NO.:

ORDERING PHYSICIAN:

PATH. NO:

NAME:

MED. REC. NO:

RECEIVE DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:BRAIN, LEFT TEMPORAL LOBE, BIOPSY EXCISION: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: Brain, left temporal lobe.

Clinical History and Pre-Op Dx: Four week history of sudden appearance of dysphasia in a patient who has no history of systemic illness or systemic neoplasia. She has not had previous surgery. Neuro-imaging studies revealed an enhancing mass in the left temporal area, attached to the dura, which is interpreted as "meningioma".

GROSS PATHOLOGY: Specimen received in two separate containers labeled with the patient's MRN and name. They both contain small fragments of soft gelatinous grayish-red tissue in which normal landmarks of brain architecture cannot be recognized. The largest one of this fragment measures approximately 2.5 x 0.7 x 0.5 cm in greatest dimensions. The entire specimen is submitted in 7 tissue cassettes.

INTRAOPERATIVE CONSULTATION:

1. Necrotizing tissue, no clear cut evidence of neoplasia.
2. Small cell, necrotizing neoplasm by

MICROSCOPIC: Fragments of brain parenchyma can be recognized in some of the sections. However, the tissue is almost completely effaced by diffuse infiltration of a neoplasm made-up of small cells that lack a clear cut architectural pattern, but occasionally are arranged in rosette-like structures. A prominent feature of this neoplasm are the numerous blood vessels, small medium-sized and large, many of which are thrombosed. Hemorrhage and coagulation necrosis are important components of this neoplasm that lacks almost entirely collagen fiber deposition. Individual neoplastic cells are approximately 8 to 10 microns in diameter, have a relatively large nucleus and very scanty cytoplasm without prominent processes. Atypical mitosis, individual cell necrosis, and nuclear pleomorphism are all easily appreciated in almost every field of this neoplasm. Intermingled with the numerous undifferentiated small cells, there are large adult astrocytes and occasional neurons that do not seem to be components of the neoplasm.

Cont'd...

[page 2 of 2]
Patient Name:

MRN:

Birth Date:

Sex: Female Room/Bed:

COMMENT: By any criteria, these neoplastic cells are classified as being highly undifferentiated. The tumor displays many features considered undesirable such as frequent mitosis, necrosis and evidence of angiogenic stimuli. The diffuse infiltrative pattern suggests a neoplasm derived from neuroectodermal elements. A follow-up report will be issued as soon as the following immunohistochemical reactions are ready: GFAP, LCA, Keratin, Synaptophysin, and MIB-1.

TISSUE COMMITTEE CODE:
BILLING CODES

ADDENDUM

Immunoperoxidase stains for leukocyte common antigen, glial fibrillary acidic protein, keratin cocktail, and MIB-1 were performed on block #4.

The great majority of neoplastic cells are not reactive with GFAP. The reactivity, when present, is weak and sparse. Star-shaped reactive astrocytes display strong immunoreactivity with GFAP. The tumor cells show no reactivity with LCA or keratins. With the MIB-1, the tumor has a very high labelling index of about 60%.

COMMENT: The immunoperoxidase stains confirm the undifferentiated nature of this glial neoplasm, namely a glioblastoma multiforme of the small cell variant. The tumor has a very high labelling index of about 60%.

Source: NCI Genomic Data Commons file 4cb19d1b-f4d2-42dc-83b7-f9185764107d (TCGA-06-0413.CAB7F061-EE5C-40E2-B1C7-F672D496928D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).